Somatic mutation profile of tumor specimen TARGET-30-PASDYT-01A (aliquot TARGET-30-PASDYT-01A-01D) from TARGET case TARGET-30-PASDYT, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Posterior mediastinum; Age at diagnosis: 1.9 years (676 days).
Specimen TARGET-30-PASDYT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c66cd846-9359-41cf-90b2-9aef0c152c7e.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASDYT-10A (Blood Derived Normal), aliquot TARGET-30-PASDYT-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fed99034-dafe-4947-ab02-1776f7a403cc

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPRE | c.1106G>C p.R369P | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.654); catalogued as COSV54552215; called by mutect2, varscan2
- TNC | c.1598C>A p.P533Q | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100406471; called by muse, mutect2, varscan2
